Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A59Y, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A59Y-01A (Primary Tumor).

[page 1 of 4]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT EXTERNAL ILIAC LYMPH NODES:
Two lymph nodes, no tumor present (0/2).
- (B) RIGHT OBTURATOR AND INTERNAL ILIAC LYMPH NODES:
Four lymph nodes, no tumor present (0/4).
- (C) LEFT EXTERNAL ILIAC LYMPH NODES:
METASTATIC PROSTATIC ADENOCARCINOMA PRESENT IN ONE OF TWO LYMPH NODES (1/2).
TUMOR FOCUS MEASURES 3.0 MM IN MAXIMUM DIMENSION.
FOCAL EXTRANODAL EXTENSION IS PRESENT.
- (D) LEFT OBTURATOR AND INTERNAL ILIAC LYMPH NODES:
METASTATIC PROSTATIC ADENOCARCINOMA PRESENT IN ONE OF TWO LYMPH NODES (1/2).
TUMOR FOCUS MEASURES 4.5 MM IN MAXIMUM DIMENSION.
FOCAL EXTRANODAL EXTENSION IS PRESENT.
- (E) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

ICD-O-3

*Path: Adenocarcinoma NOS
8140/3*

*CGCF: Adenocarcinoma,
Acinar Type 8550/3*

*Site: Prostate C61.9
91511/13*

GROSS DESCRIPTION

- (A) RIGHT EXTERNAL ILIAC LYMPH NODE – A fragment of adipose tissue containing two possible lymph nodes. Both lymph nodes are grossly free of tumor.
SECTION CODE: A1, one lymph node; A2-A5, one lymph node.
- (B) RIGHT OBTURATOR AND INTERNAL ILIAC LYMPH NODES – Two fragments of adipose tissue measuring (3.5 x 2.0 x 1.5 cm each). Four possible lymph nodes are identified. All lymph nodes are grossly free of tumor.
SECTION CODE: B1, two lymph nodes; B2, one lymph node; B3, B4, one lymph node.
- (C) LEFT EXTERNAL ILIAC LYMPH NODES – A fragment of adipose tissue measuring (6.0 x 1.0 x 1.0 cm). Two possible lymph nodes are identified. Both lymph nodes are grossly free of tumor.
SECTION CODE: C1, one lymph node, bisected; C2, C3, one lymph node, serially sectioned.
- (D) LEFT OBTURATOR AND INTERNAL ILIAC LYMPH NODES – A fragment of adipose tissue measuring (9.0 x 2.5 x 1.0 cm). Two possible lymph nodes are identified. Both lymph nodes are grossly free of tumor.
SECTION CODE: D1, one lymph node bisected; D2-D5, one lymph node, serially sectioned.
- (E) PROSTATE AND SEMINAL VESICLES – Supplemental report to follow.

CLINICAL HISTORY

None given.

SNOMED CODES

[page 2 of 4]
[REDACTED]

Start of ADDENDUM

[page 3 of 4]
ADDENDUM

This modified report is being issued to provide additional information/results.

DIAGNOSIS

(E) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4+5) (SEE COMMENT).

TUMOR EXTENDING FOCALLY INTO EXTRAPROSTATIC TISSUE.

FOCAL EXTENSION TO THE CAUTERIZED APICAL MARGIN OF RESECTION CANNOT BE EXCLUDED.

Right and left seminal vesicles, no tumor present.

TUMOR FOCALLY PRESENT IN LEFT PERIVESICULAR SOFT TISSUE.

SEE PREVIOUS REPORT FOR THE DIAGNOSIS OF THE PELVIC LYMPH NODES.

COMMENT

The prostate gland contains a single focus of prostatic adenocarcinoma. The tumor is located in the left anterolateral, left lateral, left posterolateral, left posterior, mid posterior, right posterior, right posterolateral, and right lateral peripheral zone. The tumor focus 3.0 x 2.0 cm in the largest cross-sectional dimension, and it is present in the four cross sections and extensively in the apex and base regions. The tumor exhibits extraprostatic extension in the left superior neurovascular bundle region (less than 1.0 mm). In addition, tumor is also present in left perivesicular soft tissue (less than 1.0 mm). No invasion of the seminal vesicle proper is present.

Please refer to the previous report for the diagnosis of the pelvic lymph nodes.

GROSS DESCRIPTION

(E) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (5.1 x 2.5 x 3.5 cm, 31 grams, post-fixation) has the usual shape. The soft tissue present along the right and left posterolateral aspects of the prostate appears symmetrical. A nodule is palpated on the left side of the prostate. Serial cross sections after fixation demonstrate firm areas consistent with tumor in the left lateral and left posterolateral peripheral zone of cross sections 2-4.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: E1-E4, right seminal vesicle and segment of right vas deferens from the base towards the tip; E5-E8, left seminal vesicle and segment of left vas deferens from the base towards the tip; E9, prostatic base, right border; E10, E11, prostatic base, right posterior border; E12-E17, prostatic base, central portion; E18, prostatic base, left border; E19-E21, prostatic base, left posterior border; E22, apex anterior; E23, apex left; E24, apex posterior; E25, E26, apex right; E27, detached portions of margin of resection according to the specimen radiograph; E28-E43, sections of the four cross sections of the prostate according

[page 4 of 4]
[REDACTED]

to the specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black.

Blue ink (E23-26, E29 and 31) and orange ink (E29) denote surfaces that do not represent the true margin of resection.

SNOMED CODES

-----END OF REPORT-----

HIIPAA Discrepancy		✓

Source: NCI Genomic Data Commons file 270914f7-2bfe-431f-ac15-3b068237214b (TCGA-KK-A59Y.324E4C8E-1F95-4DA6-9D1F-97E6087BA2C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).